Somatic mutation profile of tumor specimen TCGA-X6-A8C3-01A (aliquot TCGA-X6-A8C3-01A-11D-A36J-09) from TCGA case TCGA-X6-A8C3, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 59.6 years (21,751 days).
Specimen TCGA-X6-A8C3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b587fc9-7d2c-48ef-8a54-e5c5eee398df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X6-A8C3-10A (Blood Derived Normal), aliquot TCGA-X6-A8C3-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1feac8d4-f108-47ef-95b1-21d5ffb5e980

The open-access MAF lists 54 somatic variants for this specimen: 37 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 16, Splice Site 2, Frame Shift Del 2, Nonsense Mutation 1, Frame Shift Ins 1, In Frame Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACBD6 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV100852623; called by muse, mutect2
- ALPK1 | c.227A>G p.D76G | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99455369; called by muse, mutect2, varscan2
- B3GALNT2 | c.562C>T p.L188F | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV100010701; called by muse, mutect2, varscan2
- C8B | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs151070962; called by muse, mutect2, varscan2
- CACNA1C | c.967G>A p.G323R | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100223380; called by muse, mutect2, varscan2
- CCDC7 | c.4112-1G>T p.X1371_splice | Splice Site (SNP) | VAF 18/44 reads (41%) | catalogued as COSV100179435; called by muse, mutect2, varscan2
- CDKL3 | c.19C>A p.L7I | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV99528241; called by muse, mutect2
- CERT1 | c.1494+1G>T p.X498_splice (on ENST00000405807 / NM_001130105.1; = p.X370_splice on NM_005713.3) | Splice Site (SNP) | VAF 10/76 reads (13%) | catalogued as COSV99783857; called by muse, mutect2, varscan2
- CHD7 | c.820A>G p.R274G | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.122); catalogued as COSV101418566; called by muse, mutect2
- CLDN2 | c.13G>A p.G5S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV100390192; called by muse, mutect2, varscan2
- CNTNAP5 | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 60/117 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV101444371; called by muse, mutect2, varscan2
- COL4A5 | c.4001T>A p.M1334K | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT tolerated (0.91); PolyPhen benign (0.063); catalogued as COSV100090499; called by muse, mutect2, varscan2
- COLEC12 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs765394463, COSV68374660; called by muse, mutect2, varscan2
- DMD | c.9843C>A p.F3281L | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100629829; called by muse, mutect2, varscan2
- EEF1AKNMT | c.806C>T p.S269F (on ENST00000361735 / NM_015935.5; = p.S183F on NM_014955.3) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as rs1050334094, COSV100676089; called by muse, mutect2, varscan2
- IGSF3 | c.1374C>A p.S458R (on ENST00000369486 / NM_001007237.3; = p.S478R on NM_001542.4) | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.216); catalogued as COSV100605187; called by muse, mutect2, varscan2
- ITIH5 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs529874492, COSV53666803, COSV53667075; called by muse, mutect2, varscan2
- KLHL22 | c.313C>A p.L105I | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.27); catalogued as COSV100186312; called by muse, mutect2, varscan2
- LRRC8C | c.2268C>G p.Y756* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV100968516; called by muse, mutect2, varscan2
- MAP3K5 | c.2299C>T p.R767C | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs757418759, COSV62888967; called by muse, mutect2, varscan2
- MAST1 | c.1552C>T p.L518F | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99263857; called by muse, mutect2, varscan2
- MKI67 | c.3035C>A p.P1012Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV100897089, COSV64072519; called by muse, mutect2, varscan2
- PHB2 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs782273688, COSV54644320; called by muse, mutect2, varscan2
- PSMB9 | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.963); catalogued as rs1369584980, COSV100841341; called by muse, mutect2, varscan2
- SAMD9 | c.3813dup p.D1272* | Frame Shift Ins (INS) | VAF 16/76 reads (21%) | catalogued as rs748414027; called by mutect2, varscan2
- SIPA1L3 | c.3455C>T p.P1152L | Missense Mutation (SNP) | VAF 78/189 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV99730830; called by muse, mutect2, varscan2
- SLC12A4 | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99863371; called by muse, mutect2, varscan2
- SPTBN2 | c.5150C>T p.A1717V | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376579703; called by muse, mutect2, varscan2
- TGM7 | c.2108T>C p.F703S | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.761); catalogued as COSV101476911; called by muse, mutect2, varscan2
- THBS1 | c.2003A>C p.H668P | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV52953370, COSV99528548; called by muse, mutect2, varscan2
- TLR5 | c.626A>G p.Y209C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100643420; called by muse, mutect2
- TMEM132B | c.3101C>A p.P1034Q | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100171259; called by muse, mutect2, varscan2
- VAX1 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99524489; called by muse, mutect2, varscan2
- ZNF479 | c.1049A>G p.E350G | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100483169; called by muse, mutect2, varscan2
- ASTN2 | c.2482del p.V828Sfs*39 (on ENST00000313400 / NM_001365069.1; = p.V777Sfs*39 on NM_014010.5) | Frame Shift Del (DEL) | VAF 9/65 reads (14%) | called by mutect2, pindel, varscan2
- NTRK2 | c.1048_1050dup p.N350dup | In Frame Ins (INS) | VAF 17/50 reads (34%) | called by mutect2, pindel, varscan2
- SLC52A2 | c.182del p.G61Vfs*5 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | called by mutect2, pindel, varscan2
- AFAP1L2 | c.180G>A p.V60= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV100413179; called by muse, mutect2, varscan2
- BRAP | c.687A>T p.I229= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV100554343; called by muse, mutect2, varscan2
- CHDH | c.297C>T p.C99= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100179927; called by muse, mutect2, varscan2
- CNOT1 | c.5806C>T p.L1936= | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as COSV99801556; called by muse, mutect2
- CTIF | c.204G>A p.P68= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as rs577092756, COSV99838616; called by muse, mutect2, varscan2
- EML4 | c.1317C>T p.S439= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs201724206, COSV100581511; called by muse, mutect2, varscan2
- ENKUR | c.339C>A p.I113= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100482292; called by muse, mutect2
- HEPHL1 | c.1332A>G p.R444= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs761485385, COSV100244581; called by muse, mutect2, varscan2
- LCMT2 | c.126T>A p.V42= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV99980295; called by muse, mutect2, varscan2
- MYH1 | c.1935T>A p.G645= | Silent (SNP) | VAF 34/256 reads (13%) | catalogued as COSV99877161; called by muse, mutect2, varscan2
- PTPRF | c.708C>T p.I236= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100741323; called by muse, mutect2, varscan2
- RBFOX1 | c.429C>T p.I143= | Silent (SNP) | VAF 24/143 reads (17%) | catalogued as COSV100304003, COSV60958459; called by muse, mutect2, varscan2
- SGCG | c.498A>T p.R166= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV99523525; called by muse, mutect2, varscan2
- SLC12A3 | c.1485C>T p.F495= | Silent (SNP) | VAF 93/227 reads (41%) | catalogued as rs1297766065, CM081805, COSV99344906; called by muse, mutect2, varscan2
- SLC25A48 | c.198C>T p.L66= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs781729753, COSV99192015; called by muse, mutect2, varscan2
- TRPS1 | c.1950C>T p.H650= (on ENST00000220888 / NM_001330599.2; = p.H663= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/113 reads (6%) | called by muse, mutect2
- OR3A4P | n.830C>A | RNA (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2, varscan2
